Somatic mutation profile of tumor specimen MMRF_2427_1_BM_CD138pos (aliquot MMRF_2427_1_BM_CD138pos_T1_KHS5U_K15202) from MMRF case MMRF_2427, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,662 days).
Specimen MMRF_2427_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57cb1eeb-b0fa-4c2f-b992-fad33d03af17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2427_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2427_1_PB_CD3pos_C3_KHS5U_K15203; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abcd31d0-b8e7-4e6f-8f09-70f74fe72fda

The open-access MAF lists 69 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 18, Intron 8, Silent 7, 5'UTR 4, 3'Flank 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.11923C>T p.Q3975* | Nonsense Mutation (SNP) | VAF 10/300 reads (3%) | catalogued as COSV66042989; called by muse, mutect2
- C1QTNF1 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs373802984, COSV59263157; called by muse, varscan2
- DVL2 | c.1351A>G p.N451D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs756679382; called by muse, mutect2, varscan2
- GRIN2B | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.523); catalogued as rs756224637, COSV74208030; called by muse, mutect2, varscan2
- IGLV3-1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as rs555443658; called by muse, mutect2, varscan2
- IGLV4-60 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138271962; called by muse, mutect2, varscan2
- KCNJ6 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV55713468; called by muse, mutect2, varscan2
- MS4A10 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1285301068; called by muse, mutect2, varscan2
- TRPM1 | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs767656983, COSV56635782; called by muse, mutect2, varscan2
- UNCX | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as rs1463856697; called by muse, mutect2
- ZNF229 | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs778421395, COSV52161234; called by muse, mutect2, varscan2
- AOAH | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLPX | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 15/418 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2
- DNAH11 | c.5090G>A p.G1697D | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.7247A>G p.Y2416C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFCAB8 | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ERMARD | c.1609C>G p.R537G | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- FEM1A | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HAPLN1 | c.905A>G p.D302G | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HDX | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGLV1-44 | c.342C>A p.S114R | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MMP16 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NAV3 | c.3319A>G p.N1107D | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NEUROD2 | c.552C>A p.D184E | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NFKB2 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PPP2R3C | c.231A>C p.E77D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- TENT5C | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, varscan2
- USP24 | c.2297A>G p.D766G | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF850 | c.2606A>G p.Y869C | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERG | c.1230C>A p.P410= (on ENST00000398919 / NM_001243428.1; = p.P386= on NM_004449.4) | Silent (SNP) | VAF 40/168 reads (24%) | called by muse, mutect2, varscan2
- GRIK1 | c.1959G>A p.G653= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV58720033; called by muse, varscan2
- IGHV2-70 | c.66C>T p.T22= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs368498453; called by muse, mutect2, varscan2
- IGLL5 | c.79C>T p.L27= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- IHH | c.21G>A p.R7= | Silent (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2652G>C p.R884= | Silent (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2454T>C p.H818= | Silent (SNP) | VAF 48/172 reads (28%) | called by muse, mutect2, varscan2
- ABR | c.532-122C>T | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs1002856215; called by muse, mutect2, varscan2
- ACACB | c.*319G>A | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- ANO3 | c.*2844T>C | 3'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- CCDC71L | c.-14C>T | 5'UTR (SNP) | VAF 14/54 reads (26%) | catalogued as rs1015060613; called by muse, mutect2, varscan2
- CHRNA10 | c.*182G>A | 3'UTR (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- DDX23 | c.753+25C>G | Intron (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- DNAJC5 | c.*4429C>G | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- DTX4 | c.*2753G>T | 3'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- EPB41L4B | c.1409+2366C>G | Intron (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- FNBP1L | c.*1241T>G | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- FRMPD2 | c.3882-1672del | Intron (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel
- HCN1 | c.*2200A>T | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- HCN1 | c.*2153G>T | 3'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as rs924913240; called by muse, varscan2
- HOXD3 | chr2:176173774 T>C | 3'Flank (SNP) | VAF 4/82 reads (5%) | catalogued as rs1280427524; called by muse, mutect2
- ITGA5 | c.*681C>T | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- ITGA9 | c.*3833A>G | 3'UTR (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- KLF12 | c.*6210C>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- KY | c.711-2651A>G | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- MED28 | c.*6249T>C | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- MINDY2 | c.*3789C>G | 3'UTR (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- MYC | c.-376G>C | 5'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1414-48G>A | Intron (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- NSD2 | c.1410+20T>C | Intron (SNP) | VAF 13/64 reads (20%) | called by mutect2, varscan2
- PKIB | chr6:122726076 C>T | 3'Flank (SNP) | VAF 8/92 reads (9%) | catalogued as rs1191611697; called by muse, mutect2
- POLR3B | c.-111C>T | 5'UTR (SNP) | VAF 45/136 reads (33%) | catalogued as rs1328100826; called by muse, mutect2, varscan2
- RACK1 | chr5:181247464 A>C | 5'Flank (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- RGCC | c.*104C>T | 3'UTR (SNP) | VAF 61/167 reads (37%) | catalogued as rs1405392090; called by muse, mutect2, varscan2
- RSU1 | c.-93T>C | 5'UTR (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2
- SEC63 | c.*3024T>C | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- SLAMF1 | c.*1479A>G | 3'UTR (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- SPTLC2 | c.*5470G>C | 3'UTR (SNP) | VAF 33/102 reads (32%) | catalogued as rs1322694972; called by muse, varscan2
- SULT2B1 | c.826+44G>A | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- TMEM165 | c.*270T>G | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
